Somatic mutation profile of tumor specimen MP2PRT-PARTXK-TMP1-A (aliquot MP2PRT-PARTXK-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARTXK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,778 days).
Specimen MP2PRT-PARTXK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44716345-fae9-4721-9a40-4d0198e28d18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTXK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTXK-NM1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7ae3a47-a8ab-4348-afc2-0452ace1386e

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 3, Silent 2, 3'Flank 1, Intron 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.5737C>T p.R1913* | Nonsense Mutation (SNP) | VAF 56/648 reads (9%) | catalogued as rs1554237658, COSV51675024; ClinVar: pathogenic; called by muse, mutect2
- NF1 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 84/326 reads (26%) | catalogued as rs587778548, COSV62204698, COSV62222265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 170/375 reads (45%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNTNAP5 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 164/370 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs765263584; called by muse, mutect2, varscan2
- KIF21B | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 147/438 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1476570625, COSV59759853; called by muse, mutect2, varscan2
- LCE1A | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 117/597 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as rs777339865, COSV58727066, COSV58727546; called by muse, mutect2, varscan2
- SEC14L3 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 167/382 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1402541394, COSV101302995; called by muse, mutect2, varscan2
- SSTR5 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 261/705 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs777356309, COSV53512336, COSV99559790, COSV99559979; called by muse, mutect2, varscan2
- TTBK1 | c.2719G>A p.G907R | Missense Mutation (SNP) | VAF 319/726 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs781782398; called by muse, mutect2, varscan2
- AC099489.1 | c.778A>G p.R260G | Missense Mutation (SNP) | VAF 35/581 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.2); called by muse, mutect2
- ARHGEF28 | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 30/745 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHD2 | c.2685_2686insTCC p.L895_Q896insS | In Frame Ins (INS) | VAF 113/333 reads (34%) | called by mutect2, pindel, varscan2
- DNM2 | c.234A>T p.T78= | Splice Region (SNP) | VAF 38/448 reads (8%) | called by muse, mutect2
- LRBA | c.4925C>T p.S1642F | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.121); called by muse, mutect2
- PLXNA2 | c.4729G>A p.D1577N | Missense Mutation (SNP) | VAF 183/427 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC120 | c.555C>T p.S185= | Silent (SNP) | VAF 240/714 reads (34%) | catalogued as rs1557080551; called by muse, mutect2, varscan2
- POMC | c.345G>A p.P115= | Silent (SNP) | VAF 221/589 reads (38%) | catalogued as rs764382466; called by muse, varscan2
- ABI3BP | c.1577-12035G>A | Intron (SNP) | VAF 18/559 reads (3%) | catalogued as rs888050436, COSV52534180; called by muse, mutect2
- IGKV2D-24 | chr2:90005629 ins CC | 3'Flank (INS) | VAF 98/110 reads (89%) | called by mutect2, varscan2*
